CCDI case PBCNRH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/8fb99b90-1d53-4609-b173-516067a2ce23

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Retinoblastoma, NOS: ICD-O-3 morphology code: 9510/3; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 2.0 years (729 days).

Biospecimens (3 samples)
- Sample 0DWGJ3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DWGJX, 0DWGK3 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
